Surgical pathology report (de-identified scan), TCGA case TCGA-06-0145, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0145-01A (Primary Tumor).

[page 1 of 2]
PATH.NO: [REDACTED]

NAM [REDACTED]

MED. REC. NO [REDACTED]

AGE/SEX: [REDACTED] DOB: [REDACTED]

SURGERY DATE: [REDACTED]

PATIENT PHONE NO.: [REDACTED]

RECEIVE DATE: [REDACTED]

PHYSICIAN: [REDACTED]

COPY TO: [REDACTED]

PATHOLOGICAL DIAGNOSIS:

A, B. BRAIN, EXCISION: GLIOBLASTOMA MULTIFORME. MIB-1 PROLIFERATION INDEX: 9%.

SEE COMMENT.

Operation/Specimen: Brain.

Clinical History and Pre-Op Dx: [REDACTED] woman with right central tumor, with recent intratumoral hemorrhage.

GROSS PATHOLOGY: Received fresh, two fragments, 1.1 cm across in aggregate. Semi-firm, purplish red. In total #1 and 2.

INTRAOPERATIVE CONSULTATION: Brain, right central, smears: Glioma.

B.

SPECIMEN: Right central area tumor.

FIXATIVE: None.

GENERAL: Three irregular, glistening, pale tan to red-maroon soft tissue fragments, ranging from 1.0 cm. in greatest dimension to 2.0 x 1.0 x 0.4 cm. The larger fragments are sectioned.

SECTIONS: All submitted in cassettes X1-X3.
[REDACTED]

IMMUNOHISTOCHEMISTRY: Immunoperoxidase methods for GFAP, CD34 and MIB-1 were performed on sections from block # x3.

The GFAP demonstrates scant gliofibrillogenesis. The CD34 depicts extensive neovascularization with focal microvascular proliferation. With the MIB-1, a proliferation index of 9% is determined in the more cellular areas.

COMMENT: The neoplasm is a GBM with nuclear anaplasia, mitotic activity, microvascular proliferation, and necrosis with pseudopalisading.

Blocks 5, slides 5, immunostains 3.
[REDACTED]
[REDACTED]

[page 2 of 2]
[REDACTED]

ISSUE COMMITTEE CODE: [REDACTED]

ICD9: 191.1
BILLING CODES [REDACTED]

Source: NCI Genomic Data Commons file 5f0c762c-66cc-42f8-bff4-b169336a5ba0 (TCGA-06-0145.5F18975C-BF2A-4476-AD21-94FB8CA7351F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).